Somatic mutation profile of tumor specimen 0DRGF4 from CCDI case PBCALM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal sarcoma; Tissue or organ of origin: Liver; Age at diagnosis: 10.8 years (3,955 days).
Specimen 0DRGF4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04e7af5d-bcf4-4427-ac16-7b3a85e5cb7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRGEE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de48f13a-df02-49cf-a1c9-5f9d6c6d0476

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Intron 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 143/354 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KCNJ16 | c.1184A>G p.H395R | Missense Mutation (SNP) | VAF 332/634 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs371863567; called by muse, varscan2
- NBEAL2 | c.4721G>A p.R1574H | Missense Mutation (SNP) | VAF 153/564 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); catalogued as rs200266051; called by muse, varscan2
- PIWIL1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 86/501 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as rs377411680; called by muse, varscan2
- ANO8 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM155A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- KRT73 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 120/473 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- SPEF2 | c.2824G>C p.G942R | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, varscan2
- SYNE2 | c.14062C>T p.R4688* | Nonsense Mutation (SNP) | VAF 162/730 reads (22%) | called by muse, varscan2
- ACACA | c.399T>G p.S133= | Silent (SNP) | VAF 280/818 reads (34%) | called by muse, varscan2
- KCNA7 | c.66G>A p.L22= | Silent (SNP) | VAF 30/198 reads (15%) | called by muse, varscan2
- MUC3A | c.3369C>A p.S1123= | Silent (SNP) | VAF 66/512 reads (13%) | called by muse, varscan2
- OR6F1 | c.777C>T p.H259= | Silent (SNP) | VAF 65/351 reads (19%) | catalogued as rs1047241669, COSV57468087; called by muse, varscan2
- USP6 | c.3318G>A p.P1106= | Silent (SNP) | VAF 58/502 reads (12%) | catalogued as rs369094007; called by muse, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 7/53 reads (13%) | called by muse, varscan2
- IKZF1 | c.421+40A>G | Intron (SNP) | VAF 41/158 reads (26%) | called by muse, varscan2
- PRKAB1 | c.*64T>C | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, varscan2
- TAB3 | c.-23A>G | 5'UTR (SNP) | VAF 62/386 reads (16%) | called by muse, varscan2
